Somatic mutation profile of tumor specimen TCGA-ZF-AA4N-01A (aliquot TCGA-ZF-AA4N-01A-11D-A38G-08) from TCGA case TCGA-ZF-AA4N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 74.1 years (27,056 days).
Specimen TCGA-ZF-AA4N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 729f4ad4-2b8d-4a39-8b96-112ac625f0b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA4N-10A (Blood Derived Normal), aliquot TCGA-ZF-AA4N-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e55d27b9-d0a5-4bf8-baaa-066c8304cedf

The open-access MAF lists 176 somatic variants for this specimen: 134 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 39, Nonsense Mutation 12, Splice Region 3, Splice Site 3, Frame Shift Del 2, RNA 2, Translation Start Site 1, Frame Shift Ins 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>C p.X51_splice | Splice Site (SNP) | VAF 15/21 reads (71%) | hotspot (GDC flag); catalogued as rs730881677, CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SERPING1 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 17/32 reads (53%) | catalogued as rs922149386, CM960228, COSV99558128; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP2 | c.930C>G p.C310W | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57040766; called by muse, mutect2, varscan2
- AQR | c.3406C>G p.Q1136E | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50052542; called by muse, mutect2, varscan2
- ARC | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs774812713, COSV100751766; called by muse, varscan2
- ARHGEF11 | c.1593G>T p.K531N | Missense Mutation (SNP) | VAF 160/375 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63815497; called by muse, mutect2, varscan2
- ASTN2 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV57795748, COSV57816477; called by muse, varscan2
- ATP8B3 | c.1353C>A p.F451L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV100034858; called by muse, mutect2, varscan2
- BBS9 | c.1684C>T p.L562F (on ENST00000242067 / NM_001348036.1; = p.L522F on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54162648; called by muse, mutect2, varscan2
- BICD2 | c.2078T>C p.L693P | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63550854; called by muse, mutect2, varscan2
- CABS1 | c.211A>T p.K71* | Nonsense Mutation (SNP) | VAF 31/52 reads (60%) | catalogued as rs1374132825, COSV99909153; called by muse, mutect2, varscan2
- CARMIL2 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58031725; called by muse, varscan2
- CBFA2T3 | c.380-2A>C p.X127_splice | Splice Site (SNP) | VAF 26/72 reads (36%) | catalogued as COSV51932641; called by muse, mutect2, varscan2
- CCNL1 | c.194C>G p.S65W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55817212, COSV99904293; called by muse, mutect2, varscan2
- CELA3B | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs1298245114, COSV100448848; called by muse, mutect2, varscan2
- CLCN6 | c.456G>A p.P152= | Splice Region (SNP) | VAF 17/66 reads (26%) | catalogued as rs755607059, COSV56742979; called by muse, mutect2, varscan2
- CLUH | c.130C>G p.Q44E (on ENST00000435359; = p.Q82E on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1438360627, COSV70930047; called by muse, mutect2
- CNTN3 | c.1850C>A p.S617Y | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55180408, COSV55184908; called by muse, mutect2, varscan2
- COL14A1 | c.5254C>T p.P1752S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV52847666; called by muse, mutect2, varscan2
- COL6A6 | c.6032C>T p.A2011V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62036815; called by muse, mutect2, varscan2
- COPZ1 | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV50433483; called by muse, mutect2, varscan2
- CREBBP | c.2163G>A p.M721I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as COSV52140180, COSV52146867; called by muse, mutect2, varscan2
- CSMD3 | c.4825C>G p.P1609A (on ENST00000297405 / NM_001363185.1; = p.P1505A on NM_052900.3) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52313045; called by muse, mutect2, varscan2
- DCST1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs746859509, COSV55062961; called by muse, mutect2, varscan2
- DDX24 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58213820; called by muse, mutect2, varscan2
- DESI2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99798352; called by muse, mutect2
- DGKB | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164942783, COSV51803524; called by muse, mutect2, varscan2
- DLL4 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.031); catalogued as COSV51071575; called by muse, mutect2, varscan2
- DMD | c.6112C>G p.L2038V | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63790287; called by muse, mutect2, varscan2
- DMRT1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT tolerated (0.68); PolyPhen benign (0.056); catalogued as rs200217569, COSV66524601; called by muse, mutect2, varscan2
- DNMT1 | c.4776C>G p.I1592M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61583633; called by muse, mutect2, varscan2
- EBF1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs775985452, COSV58194567; called by muse, mutect2, varscan2
- ESPL1 | c.4691C>G p.S1564* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV57765037; called by muse, mutect2, varscan2
- FADS2 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV53902300; called by muse, mutect2, varscan2
- FNDC3B | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100393814, COSV61049434; called by muse, mutect2, varscan2
- GABRE | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 49/59 reads (83%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.864); catalogued as COSV64821290; called by muse, mutect2, varscan2
- GABRR2 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754042657, COSV68765110, COSV68766312; called by muse, mutect2, varscan2
- GTF2I | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs1554401414, COSV60403834; called by muse, mutect2, varscan2
- HIPK2 | c.1929G>C p.Q643H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV61232513; called by muse, mutect2, varscan2
- HPS6 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1323195795, COSV54626684; called by muse, varscan2
- HPS6 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV54626694; called by muse, varscan2
- HPS6 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs757912066, COSV54626708; called by muse, mutect2
- HPS6 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs763543056, COSV54626720; called by muse, mutect2, varscan2
- IFT46 | c.247C>T p.Q83* (on ENST00000264021 / NM_001168618.2; = p.Q134* on NM_020153.3) | Nonsense Mutation (SNP) | VAF 5/79 reads (6%) | catalogued as COSV99871182; called by muse, mutect2
- ITGA2B | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52235031; called by muse, mutect2, varscan2
- JMJD4 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs763227625, COSV59920149; called by muse, mutect2, varscan2
- KEAP1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV50260398, COSV50261323, COSV50261936; called by muse, mutect2, varscan2
- KMT2D | c.14563G>C p.D4855H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV56484789; called by muse, mutect2, varscan2
- KMT2D | c.14080G>T p.E4694* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99985117; called by muse, mutect2, varscan2
- KRTAP5-6 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 99/204 reads (49%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.038); catalogued as COSV66289383; called by muse, mutect2, varscan2
- LAMB3 | c.3363G>C p.E1121D | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as rs780324954, COSV50526217; called by muse, mutect2, varscan2
- LARP1 | c.2029A>C p.K677Q (on ENST00000518297 / NM_033551.3; = p.K600Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.186); catalogued as COSV60431217; called by muse, mutect2, varscan2
- LATS1 | c.2521C>T p.H841Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53599669; called by muse, mutect2, varscan2
- LDHAL6A | c.640C>A p.L214M | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52652796; called by muse, mutect2, varscan2
- LPAR3 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs367984690, COSV65455083; called by muse, mutect2, varscan2
- LRP4 | c.5679G>C p.W1893C | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV66138600; called by muse, mutect2, varscan2
- LRRN1 | c.1807C>T p.Q603* | Nonsense Mutation (SNP) | VAF 49/133 reads (37%) | catalogued as COSV100076530; called by muse, mutect2, varscan2
- MDN1 | c.9283C>T p.H3095Y | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV65530014; called by muse, mutect2, varscan2
- MESP2 | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs1323955354, COSV59093619; called by muse, mutect2, varscan2
- MKS1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as CM112366, COSV58306164; called by muse, mutect2, varscan2
- MUC5AC | c.15723C>T p.L5241= | Splice Region (SNP) | VAF 40/81 reads (49%) | catalogued as rs773274173, COSV64369312; called by muse, mutect2, varscan2
- MYH9 | c.4661C>T p.A1554V | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV53392891; called by muse, mutect2
- NAP1L3 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV100220595, COSV59076064; called by muse, mutect2
- NOSTRIN | c.766G>C p.D256H (on ENST00000317647 / NM_001039724.4; = p.D178H on NM_052946.3) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58324052; called by muse, mutect2, varscan2
- NPFFR2 | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV58154182; called by muse, mutect2
- NPFFR2 | c.940A>T p.N314Y | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV58154195; called by muse, mutect2
- NRG3 | c.1844G>A p.G615E (on ENST00000404547 / NM_001370084.1; = p.G591E on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.866); catalogued as COSV64548311; called by muse, mutect2, varscan2
- NWD1 | c.2101C>G p.L701V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.112); catalogued as rs767493015, COSV60351293; called by muse, mutect2, varscan2
- OR5B12 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs139365126; called by muse, mutect2, varscan2
- PCSK7 | c.1536C>T p.V512= | Splice Region (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99639184; called by muse, mutect2, varscan2
- PEX19 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV63620040; called by muse, mutect2, varscan2
- PIGU | c.822C>G p.F274L | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54163542, COSV54166324; called by muse, mutect2, varscan2
- PIGZ | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs368275616; called by muse, mutect2, varscan2
- PISD | c.399C>G p.H133Q (on ENST00000439502 / NM_001326412.1; = p.H99Q on NM_014338.3) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV56718809; called by muse, mutect2, varscan2
- PLD1 | c.1648G>T p.G550* | Nonsense Mutation (SNP) | VAF 38/102 reads (37%) | catalogued as COSV100578694; called by muse, mutect2, varscan2
- PLEC | c.11791G>A p.E3931K (on ENST00000322810 / NM_201380.4; = p.E3821K on NM_000445.5) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs782456612, COSV100517989; called by muse, mutect2, varscan2
- PLEC | c.4630G>A p.A1544T (on ENST00000322810 / NM_201380.4; = p.A1434T on NM_000445.5) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV100517996; called by muse, mutect2, varscan2
- PLEKHA7 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs772989794, COSV63050832; called by muse, mutect2, varscan2
- PML | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV51454108; called by muse, mutect2, varscan2
- POLR3E | c.1154T>A p.F385Y | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV55403428; called by muse, mutect2, varscan2
- PPP1R13L | c.2380G>C p.E794Q | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62909674; called by muse, mutect2, varscan2
- PPP2R2A | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV60099081; called by muse, mutect2, varscan2
- PPP4R1 | c.2261G>A p.R754K (on ENST00000400556 / NM_001042388.3; = p.R737K on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs1345570295, COSV53284524; called by muse, varscan2
- PRKD1 | c.2459T>C p.L820P | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59585902; called by muse, mutect2, varscan2
- PRKD1 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs749621467, COSV59578015, COSV59585923; called by muse, mutect2, varscan2
- PUS7 | c.1176-1G>A p.X392_splice | Splice Site (SNP) | VAF 28/95 reads (29%) | catalogued as COSV62678416; called by muse, varscan2
- RECQL4 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1420581482, COSV99468089; called by muse, mutect2, varscan2
- REXO1 | c.3169C>T p.H1057Y | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as rs377467891; called by muse, mutect2, varscan2
- RHCG | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51518366; called by muse, mutect2, varscan2
- RNGTT | c.1475G>C p.G492A | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55655286, COSV55659995; called by muse, mutect2, varscan2
- ROBO1 | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs1428266247, COSV71393672; called by muse, mutect2, varscan2
- RPAP2 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV101532184; called by muse, mutect2, varscan2
- RPF1 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1347010034, COSV65724765; called by muse, mutect2, varscan2
- RPS20 | c.164G>C p.R55P | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV50537135; called by muse, mutect2, varscan2
- RYR3 | c.5600G>A p.R1867H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759927306, COSV101213979, COSV66781047; called by muse, varscan2
- SCN1A | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs145670933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCUBE3 | c.2038C>G p.P680A | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.998); catalogued as COSV51460457; called by muse, mutect2, varscan2
- SEC16B | c.2416C>G p.L806V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.084); catalogued as COSV57629937; called by muse, mutect2, varscan2
- SEH1L | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50818292; called by muse, mutect2
- SERPINB7 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV60535706; called by muse, mutect2, varscan2
- SLC2A2 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1441375275, COSV58588517; called by muse, mutect2, varscan2
- SLC38A3 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68844166; called by muse, mutect2, varscan2
- SLMAP | c.1993G>A p.E665K (on ENST00000428312 / NM_001377924.1; = p.E727K on NM_007159.5) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.997); catalogued as COSV55853240; called by muse, mutect2, varscan2
- SMTNL2 | c.689G>A p.S230N (on ENST00000389313 / NM_001114974.2; = p.S86N on NM_198501.3) | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as COSV58809097; called by muse, mutect2, varscan2
- SPOP | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV61652698, COSV61653164; called by muse, mutect2, varscan2
- SPSB3 | c.691C>A p.L231I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51602942; called by muse, mutect2, varscan2
- TAF1L | c.3666G>T p.E1222D | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV54268867; called by muse, mutect2
- TENM3 | c.3493G>C p.G1165R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV69318861; called by muse, mutect2, varscan2
- TFRC | c.907C>A p.L303M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as rs1435725519, COSV64056441; called by muse, mutect2, varscan2
- TGFBR2 | c.730A>T p.I244F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55459661; called by muse, mutect2, varscan2
- TMEM132A | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV50021817; called by muse, mutect2, varscan2
- TMEM87A | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.153); catalogued as COSV56199250; called by muse, mutect2, varscan2
- TNN | c.2963G>T p.G988V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV53435182; called by muse, mutect2, varscan2
- TOMM40L | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100915836; called by muse, mutect2, varscan2
- TRAPPC3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV64264597; called by muse, mutect2, varscan2
- TREH | c.966C>G p.F322L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99874759; called by muse, mutect2, varscan2
- USP37 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV51447186; called by muse, mutect2, varscan2
- VCAM1 | c.898A>T p.N300Y | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV54121900; called by muse, mutect2, varscan2
- VPS13B | c.5696A>G p.D1899G | Missense Mutation (SNP) | VAF 6/158 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as COSV62156338; called by muse, mutect2
- YWHAZ | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.337); catalogued as rs775309705, COSV62053401; called by muse, mutect2, varscan2
- ZMYND15 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52644721; called by muse, mutect2, varscan2
- ZNF391 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55124919; called by muse, mutect2
- ZNF404 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60987449, COSV60988865; called by muse, mutect2, varscan2
- ZNF462 | c.7207G>A p.D2403N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52950501; called by muse, mutect2, varscan2
- ZNF492 | c.448T>A p.F150I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV101514048; called by muse, mutect2, varscan2
- ZNF527 | c.922G>T p.G308* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100648768, COSV62235166; called by muse, mutect2, varscan2
- NPAS2 | c.1_5del p.M1_?2 | Translation Start Site (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- SCAI | c.479_480del p.R160Ifs*8 (on ENST00000336505 / NM_001144877.3; = p.R183Ifs*8 on NM_173690.5) | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by pindel, varscan2
- TPM4 | c.161_163del p.R54del (on ENST00000300933; = p.E62del on NM_003290.3) | In Frame Del (DEL) | VAF 16/53 reads (30%) | called by pindel, varscan2
- TRBV19 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZEB2 | c.255dup p.D86Rfs*2 | Frame Shift Ins (INS) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- ZNF180 | c.1921del p.T641Hfs*4 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | called by mutect2, pindel, varscan2
- ATP13A5 | c.639C>T p.F213= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV60875198; called by muse, mutect2, varscan2
- BNC2 | c.2784G>A p.G928= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs1563774541, COSV66175891; called by muse, mutect2, varscan2
- CASKIN2 | c.1272C>G p.G424= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100050806; called by muse, mutect2
- CRISPLD2 | c.261G>A p.E87= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs780264740, COSV52282997; called by muse, mutect2, varscan2
- DUSP21 | c.378C>A p.S126= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV100173652; called by muse, mutect2
- ENPP5 | c.1311C>T p.V437= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs756673571, COSV57909900; called by muse, mutect2, varscan2
- FUCA2 | c.474G>A p.K158= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV50019688, COSV50021024; called by muse, mutect2, varscan2
- FZD2 | c.1536G>A p.P512= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs1383642373, COSV59530182; called by muse, mutect2, varscan2
- G2E3 | c.990C>T p.S330= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV52842785; called by muse, mutect2
- GDF15 | c.735G>C p.P245= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV53251339, COSV99416340; called by muse, mutect2, varscan2
- GRIN3A | c.2229G>A p.R743= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV62458028; called by muse, mutect2, varscan2
- INA | c.234C>T p.S78= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1277289082, COSV63976544; called by muse, mutect2, varscan2
- KLHL4 | c.360T>C p.C120= | Silent (SNP) | VAF 49/64 reads (77%) | catalogued as COSV64147717; called by muse, mutect2, varscan2
- LCE1F | c.195T>G p.G65= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs779628409, COSV57670204; called by muse, mutect2, varscan2
- LIN9 | c.1470C>T p.D490= (on ENST00000366808 / NM_001270410.2; = p.D435= on NM_173083.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV60246969; called by muse, mutect2, varscan2
- MARK2 | c.168C>G p.L56= | Silent (SNP) | VAF 40/73 reads (55%) | catalogued as COSV59288908; called by muse, mutect2, varscan2
- MTFR1L | c.276C>T p.P92= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as COSV65356496; called by muse, mutect2, varscan2
- NLRP8 | c.906G>A p.L302= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV52593521; called by muse, mutect2, varscan2
- NOD2 | c.510C>T p.I170= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs1361785600, COSV56054721; called by muse, mutect2, varscan2
- PCNX3 | c.855G>A p.R285= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100482691; called by muse, mutect2
- POLQ | c.471C>G p.L157= | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as COSV51760984; called by muse, mutect2, varscan2
- PPP1R3A | c.540A>G p.S180= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV52892755; called by muse, mutect2, varscan2
- PRKDC | c.8052G>A p.R2684= | Silent (SNP) | VAF 75/233 reads (32%) | catalogued as rs532963775, COSV58063190; called by muse, mutect2, varscan2
- RITA1 | c.273C>G p.T91= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1382511932, COSV100014101, COSV100014117; called by muse, mutect2, varscan2
- RSPH14 | c.510C>T p.F170= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV53272026; called by muse, mutect2, varscan2
- SHISAL1 | c.168C>T p.F56= | Silent (SNP) | VAF 92/217 reads (42%) | catalogued as COSV66988828; called by muse, mutect2, varscan2
- SIX6 | c.141C>T p.L47= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs756246855, COSV59803617; called by muse, mutect2, varscan2
- SLC10A5 | c.459G>A p.L153= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV101594257, COSV72828487; called by muse, mutect2, varscan2
- SNRPD2 | c.9C>A p.L3= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV50004860; called by muse, varscan2
- SPTBN5 | c.2880G>C p.L960= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV58019596, COSV58027821; called by muse, mutect2, varscan2
- TEP1 | c.1149G>A p.R383= | Silent (SNP) | VAF 65/127 reads (51%) | catalogued as rs1291627175, COSV52991229; called by muse, mutect2, varscan2
- TLX1 | c.822C>A p.I274= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV64622864; called by muse, mutect2, varscan2
- TMEM101 | c.96C>T p.F32= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV52814145; called by muse, mutect2, varscan2
- TOP2B | c.4641G>A p.R1547= (on ENST00000264331 / NM_001330700.2; = p.R1542= on NM_001068.3) | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99980192; called by muse, mutect2
- TWNK | c.471C>T p.I157= | Silent (SNP) | VAF 48/158 reads (30%) | catalogued as COSV52971988; called by muse, mutect2, varscan2
- VCAN | c.3597C>T p.I1199= | Silent (SNP) | VAF 53/94 reads (56%) | catalogued as rs1287784350, COSV54116257; called by muse, mutect2, varscan2
- VWA3A | c.1842C>A p.L614= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1374201811, COSV55394853; called by muse, mutect2, varscan2
- WASF3 | c.529A>C p.R177= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV58971609; called by muse, mutect2, varscan2
- ZNF667 | c.93G>C p.L31= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV52639252; called by muse, mutect2, varscan2
- AP001042.1 | n.2559C>G | RNA (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- C12orf76 | n.570G>T | RNA (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100472958, COSV100473043; called by muse, mutect2, varscan2
- MECOM | c.-221A>G | 5'UTR (SNP) | VAF 34/116 reads (29%) | catalogued as COSV99245202; called by muse, mutect2, varscan2
